Somatic mutation profile of tumor specimen MMRF_2821_1_BM_CD138pos (aliquot MMRF_2821_1_BM_CD138pos_T1_KHS5U_L15707) from MMRF case MMRF_2821, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.7 years (20,327 days).
Specimen MMRF_2821_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6f08ee2-28b7-49b7-93ec-535a9bb48dd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2821_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2821_1_PB_WBC_C2_KHS5U_L15753; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68324135-4ac3-495a-8f27-521430253a77

The open-access MAF lists 58 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 11, Silent 7, Intron 6, Nonsense Mutation 4, Frame Shift Del 3, 5'Flank 2, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 48/92 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDK11B | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs759406847; called by muse, mutect2, varscan2
- CNTN6 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762861042, COSV63182381; called by muse, mutect2, varscan2
- EDN1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1239711154; called by muse, mutect2, varscan2
- ENTPD8 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 57/195 reads (29%) | catalogued as rs1193454265, COSV58162370; called by muse, mutect2, varscan2
- GAB2 | c.601C>T p.R201* (on ENST00000361507 / NM_080491.3; = p.R163* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1465572548; called by muse, mutect2, varscan2
- GALNT8 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs181113647; called by muse, mutect2, varscan2
- GNAT3 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs368632002; called by muse, mutect2
- IGHV2-70 | c.241A>T p.S81C | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs374373498; called by muse, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGLV2-14 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as rs532607004; called by muse, varscan2
- KDM4C | c.3069_3070del p.R1024Sfs*7 | Frame Shift Del (DEL) | VAF 71/275 reads (26%) | catalogued as rs1239554866; called by mutect2, pindel, varscan2
- LINGO1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100796351; called by muse, mutect2, varscan2
- NFKBIA | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV53754138; called by muse, mutect2, varscan2
- SCN9A | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1313500117; called by muse, mutect2, varscan2
- SPIRE2 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs533792288, COSV54526870; called by muse, mutect2, varscan2
- ALG10 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BCL7A | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP4V2 | c.1019G>C p.W340S | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- DPY19L3 | c.926T>A p.M309K | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSCAM | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MAGEL2 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 99/297 reads (33%) | called by muse, mutect2, varscan2
- PATJ | c.5025G>C p.R1675S | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PIK3AP1 | c.948_951del p.F317Efs*10 | Frame Shift Del (DEL) | VAF 46/109 reads (42%) | called by mutect2, pindel, varscan2
- TMEM151A | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMEM30B | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRAF3 | c.917del p.K306Rfs*17 | Frame Shift Del (DEL) | VAF 34/50 reads (68%) | called by mutect2, pindel, varscan2
- ZNF415 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZNF665 | c.585A>T p.K195N (on ENST00000600412; = p.K260N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BMERB1 | c.153G>A p.E51= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV55508026; called by muse, mutect2, varscan2
- CAV2 | c.30A>G p.V10= | Silent (SNP) | VAF 83/238 reads (35%) | catalogued as rs1300545994; called by muse, mutect2, varscan2
- CBARP | c.2010G>A p.G670= | Silent (SNP) | VAF 55/154 reads (36%) | called by muse, mutect2, varscan2
- KIAA1217 | c.3120G>T p.L1040= | Silent (SNP) | VAF 70/158 reads (44%) | called by muse, mutect2, varscan2
- KIAA1549 | c.5229G>A p.T1743= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs933271585, COSV54303760, COSV54309135; called by muse, mutect2, varscan2
- KNDC1 | c.90C>T p.L30= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as rs765671879; called by muse, mutect2, varscan2
- ZFP36L1 | c.408G>A p.Q136= | Silent (SNP) | VAF 186/415 reads (45%) | called by muse, mutect2, varscan2
- AADACL3 | c.-1C>A | 5'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- CASK | chrX:41518864 T>A | 3'Flank (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- CMC4 | c.*153C>T | 3'UTR (SNP) | VAF 45/45 reads (100%) | called by muse, mutect2, varscan2
- DLL4 | c.*174T>G | 3'UTR (SNP) | VAF 51/158 reads (32%) | called by muse, mutect2, varscan2
- ERAP2 | chr5:96873607 A>G | 5'Flank (SNP) | VAF 52/188 reads (28%) | called by muse, mutect2, varscan2
- GABPB1 | c.1035+107A>G | Intron (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- HIRIP3 | chr16:29995659 C>G | 5'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- IVNS1ABP | c.*187T>A | 3'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- KLHL14 | c.*85C>A | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- MTUS1 | c.*1038C>G | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- NOVA1 | c.*1391C>A | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- NRG3 | c.824-191991T>G | Intron (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- PDE4B | c.281+73843C>T | Intron (SNP) | VAF 42/103 reads (41%) | catalogued as rs771932029; called by muse, mutect2, varscan2
- PI4K2B | c.*1134del | 3'UTR (DEL) | VAF 46/190 reads (24%) | called by mutect2, pindel, varscan2
- PTGS2 | c.*2497_*2500del | 3'UTR (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- SCUBE2 | c.256+112C>T | Intron (SNP) | VAF 48/115 reads (42%) | catalogued as rs958500183; called by muse, mutect2, varscan2
- SIGLEC5 | c.*237G>T | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- SLMAP | c.1336+2824T>G | Intron (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2
- TMEM52B | c.*1413del | 3'UTR (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- TRIQK | chr8:92883801 T>C | 3'Flank (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- TTN | c.10303+2417T>C | Intron (SNP) | VAF 99/240 reads (41%) | called by muse, mutect2, varscan2
- ZNF681 | c.*3458C>T | 3'UTR (SNP) | VAF 40/152 reads (26%) | catalogued as rs991071240; called by muse, mutect2, varscan2
